Somatic mutation profile of cancer-model specimen HCM-SANG-0297-C15-85A (3D Organoid; aliquot HCM-SANG-0297-C15-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0297-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0297-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3ea19b3-a0d2-4ba5-9963-72106281cb73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0297-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0297-C15-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90996c3f-34f4-47c4-9d0e-c36dc2f1b01c

The open-access MAF lists 165 somatic variants for this specimen: 120 protein-altering or splice-affecting, 40 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 102, Silent 40, Nonsense Mutation 7, Frame Shift Ins 3, Frame Shift Del 3, Intron 2, Splice Site 2, Splice Region 2, 3'Flank 1, 3'UTR 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB4 | c.2393T>C p.L798P | Missense Mutation (SNP) | VAF 292/292 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100725903, COSV61483358, COSV61493836; called by muse, mutect2, varscan2
- AASS | c.428G>C p.R143T | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as COSV62789641; called by muse, mutect2, varscan2
- ADGRB1 | c.3541G>A p.V1181I | Missense Mutation (SNP) | VAF 170/452 reads (38%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.956); catalogued as rs772937459; called by muse, mutect2, varscan2
- APC2 | c.4564G>A p.A1522T | Missense Mutation (SNP) | VAF 434/645 reads (67%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs375010507; called by muse, varscan2
- APLP2 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 178/178 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1212536922, COSV53842237; called by muse, mutect2, varscan2
- ARHGEF15 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 121/364 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as rs1451448716; called by muse, mutect2, varscan2
- BTBD10 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 147/291 reads (51%) | catalogued as COSV99533629; called by muse, mutect2, varscan2
- C10orf53 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 124/265 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs369717123; called by muse, mutect2, varscan2
- C4orf50 | c.269G>A p.R90H (on ENST00000324058; = p.R1322H on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/388 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs776133301, COSV100136140; called by muse, mutect2
- CACNA2D2 | c.3036C>G p.S1012R (on ENST00000479441 / NM_001174051.3; = p.S1005R on NM_006030.4) | Missense Mutation (SNP) | VAF 100/488 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1208916332; called by muse, mutect2, varscan2
- CDH10 | c.2198T>G p.L733R | Missense Mutation (SNP) | VAF 177/503 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100050052; called by muse, mutect2, varscan2
- CDKN2A | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 141/476 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM980322, COSV58684053, COSV58729667; called by muse, mutect2, varscan2
- CPSF3 | c.1875C>G p.D625E | Missense Mutation (SNP) | VAF 143/152 reads (94%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV99432476; called by muse, mutect2, varscan2
- DDX46 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 42/230 reads (18%) | catalogued as rs746734262; called by muse, mutect2, varscan2
- DSG3 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 267/267 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99934706; called by muse, mutect2, varscan2
- E2F4 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 124/338 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs757259236; called by muse, mutect2, varscan2
- EYS | c.6485A>C p.K2162T | Missense Mutation (SNP) | VAF 84/136 reads (62%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as rs1039415909; called by muse, mutect2, varscan2
- GNAS | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 98/983 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs773471190, COSV58331036; called by muse, mutect2, varscan2
- GORASP1 | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 304/502 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766833329, COSV57188379; called by muse, mutect2, varscan2
- HDX | c.2021C>T p.T674I | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs769373598; called by muse, mutect2, varscan2
- HP | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 100/276 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs769677847; called by muse, mutect2, varscan2
- HYPK | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 180/180 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs372106020; called by muse, mutect2, varscan2
- ITGA6 | c.2051G>A p.R684Q (on ENST00000442250; = p.R645Q on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/148 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs190444302; called by muse, mutect2, varscan2
- KCNA5 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 84/390 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV52906292; called by muse, mutect2, varscan2
- KDM6A | c.1792A>G p.I598V | Missense Mutation (SNP) | VAF 346/346 reads (100%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs762004743, COSV65039921; called by muse, mutect2, varscan2
- LEFTY1 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 64/611 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773412175; called by muse, mutect2, varscan2
- MEGF6 | c.3427G>A p.V1143I | Missense Mutation (SNP) | VAF 93/539 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.047); catalogued as rs942388766, COSV99621435; called by muse, mutect2, varscan2
- MKI67 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 26/398 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV100896974; called by muse, mutect2
- NPM2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 215/321 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV57075073; called by muse, mutect2, varscan2
- NTNG1 | c.491A>C p.K164T | Missense Mutation (SNP) | VAF 53/347 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53961731; called by muse, mutect2, varscan2
- P4HTM | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 361/514 reads (70%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.759); catalogued as rs372623573; called by muse, mutect2, varscan2
- PCDH11Y | c.3316G>A p.D1106N | Missense Mutation (SNP) | VAF 90/109 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99291559; called by muse, mutect2, varscan2
- PITPNM1 | c.3539C>T p.S1180L | Missense Mutation (SNP) | VAF 55/398 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs894148416, COSV99653773; called by muse, mutect2, varscan2
- PTPN21 | c.2051G>A p.R684Q | Missense Mutation (SNP) | VAF 151/511 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1351469317; called by muse, mutect2, varscan2
- RELB | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 464/485 reads (96%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs376331542, COSV55512134; called by muse, mutect2, varscan2
- RIMS2 | c.2943C>A p.S981R (on ENST00000666250 / NM_001348490.2; = p.S789R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 139/295 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.844); catalogued as rs1251912528; called by muse, mutect2, varscan2
- SEPTIN12 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs140916588; called by muse, mutect2, varscan2
- SLC2A6 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 261/384 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs878916227; called by muse, mutect2, varscan2
- SPNS1 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 73/547 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1280604602, COSV57954340; called by muse, mutect2, varscan2
- SYNE1 | c.217C>A p.Q73K | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs774912325, COSV55053978; called by muse, varscan2
- TP53 | c.956del p.K319Rfs*26 | Frame Shift Del (DEL) | VAF 179/251 reads (71%) | catalogued as COSV53486415; called by mutect2, pindel, varscan2
- UBQLN3 | c.433T>G p.L145V | Missense Mutation (SNP) | VAF 262/447 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as COSV104411257; called by muse, mutect2, varscan2
- UBR5 | c.7906del p.R2636Gfs*10 | Frame Shift Del (DEL) | VAF 121/345 reads (35%) | catalogued as COSV55290368; called by mutect2, pindel, varscan2
- VCAN | c.2857G>A p.A953T | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV54115135; called by muse, mutect2, varscan2
- ZFP28 | c.739C>G p.P247A | Missense Mutation (SNP) | VAF 169/177 reads (95%) | SIFT tolerated (0.13); PolyPhen benign (0.184); catalogued as rs544442408, COSV100019783; called by muse, mutect2, varscan2
- ZIC2 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 62/705 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as rs778049889, CM091702; called by muse, mutect2
- ZNF43 | c.516dup p.L173Tfs*21 | Frame Shift Ins (INS) | VAF 58/172 reads (34%) | catalogued as rs748612562; called by mutect2, varscan2
- ZNF469 | c.7179C>A p.D2393E (on ENST00000437464; = p.D2421E on NM_001367624.2) | Missense Mutation (SNP) | VAF 66/622 reads (11%) | SIFT tolerated (0.85); PolyPhen benign (0.061); catalogued as rs1213989862; called by muse, mutect2, varscan2
- ZSCAN18 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 108/335 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs754820236, COSV53730451; called by muse, mutect2, varscan2
- APBB2 | c.181A>G p.S61G | Missense Mutation (SNP) | VAF 202/459 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- AVL9 | c.1035A>C p.K345N | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.258); called by muse, mutect2
- C11orf53 | c.495C>G p.D165E | Missense Mutation (SNP) | VAF 90/204 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- CABS1 | c.670A>C p.S224R | Missense Mutation (SNP) | VAF 134/262 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CAMTA2 | c.3519G>T p.M1173I | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCR9 | c.281A>T p.D94V (on ENST00000357632 / NM_031200.3; = p.D82V on NM_006641.4) | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP54 | c.8854T>A p.L2952I | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- CNKSR2 | c.941A>C p.K314T | Missense Mutation (SNP) | VAF 230/230 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- COL21A1 | c.44T>G p.L15R | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- DAZL | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 29/228 reads (13%) | called by muse, mutect2, varscan2
- DBN1 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 78/792 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DNAH8 | c.3278A>G p.K1093R | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- DYRK2 | c.484C>T p.Q162* (on ENST00000344096 / NM_006482.3; = p.Q89* on NM_003583.4) | Nonsense Mutation (SNP) | VAF 72/251 reads (29%) | called by muse, mutect2, varscan2
- EGLN3 | c.668A>C p.K223T | Missense Mutation (SNP) | VAF 158/282 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ENTPD8 | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 87/308 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ERMN | c.450A>T p.K150N | Missense Mutation (SNP) | VAF 308/309 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- FAT2 | c.7906A>C p.I2636L | Missense Mutation (SNP) | VAF 253/253 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- FAT2 | c.7811T>G p.V2604G | Missense Mutation (SNP) | VAF 335/335 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- GALNT17 | c.1325A>G p.K442R | Missense Mutation (SNP) | VAF 181/498 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HIVEP1 | c.1249A>T p.K417* | Nonsense Mutation (SNP) | VAF 133/279 reads (48%) | called by muse, mutect2, varscan2
- KCNE3 | c.79A>C p.S27R | Missense Mutation (SNP) | VAF 54/2032 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- LDLRAD3 | c.362A>C p.K121T | Missense Mutation (SNP) | VAF 94/476 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- LIMD1 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 132/417 reads (32%) | called by muse, mutect2, varscan2
- LINGO2 | c.1715A>G p.K572R | Missense Mutation (SNP) | VAF 33/273 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MMP16 | c.339T>G p.F113L | Missense Mutation (SNP) | VAF 95/374 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MPRIP | c.2540C>T p.A847V | Missense Mutation (SNP) | VAF 266/269 reads (99%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- NAA35 | c.627G>A p.K209= | Splice Region (SNP) | VAF 51/151 reads (34%) | called by muse, mutect2, varscan2
- NEK8 | c.2049A>G p.R683= | Splice Region (SNP) | VAF 29/359 reads (8%) | called by muse, mutect2
- NOX4 | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 22/476 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- NOXRED1 | c.496G>T p.V166L | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- NPHP4 | c.783G>T p.E261D | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- NRG3 | c.5G>T p.S2I | Missense Mutation (SNP) | VAF 55/92 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- OR6C70 | c.98G>A p.C33Y | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- PANX1 | c.906G>C p.K302N | Missense Mutation (SNP) | VAF 43/720 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2
- PCDH11X | c.824A>T p.D275V | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDGFRA | c.348C>G p.H116Q | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PLCH1 | c.1021C>T p.R341C (on ENST00000340059 / NM_001130960.2; = p.R353C on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/249 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R42 | c.305dup p.G103Rfs*22 | Frame Shift Ins (INS) | VAF 159/378 reads (42%) | called by mutect2, pindel, varscan2
- PPP4R1 | c.2140C>G p.L714V (on ENST00000400556 / NM_001042388.3; = p.L697V on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/309 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- PRAMEF1 | c.1009C>A p.L337I | Missense Mutation (SNP) | VAF 53/464 reads (11%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRAMEF4 | c.863A>T p.D288V | Missense Mutation (SNP) | VAF 65/230 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- PRKDC | c.5071C>T p.Q1691* | Nonsense Mutation (SNP) | VAF 15/281 reads (5%) | called by muse, mutect2
- PRR36 | c.2422T>G p.S808A | Missense Mutation (SNP) | VAF 52/606 reads (9%) | SIFT tolerated (0.82); called by muse, mutect2
- PTPN5 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 162/311 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- PXDNL | c.2718A>T p.E906D | Missense Mutation (SNP) | VAF 234/448 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- RBM23 | c.865A>G p.I289V (on ENST00000359890 / NM_001077351.2; = p.I273V on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/81 reads (100%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- RBM48 | c.265G>C p.V89L | Missense Mutation (SNP) | VAF 18/596 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RORA | c.416C>T p.S139F (on ENST00000335670 / NM_134261.3; = p.S164F on NM_002943.3) | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RPP14 | c.319-1G>A p.X107_splice | Splice Site (SNP) | VAF 81/211 reads (38%) | called by muse, mutect2, varscan2
- SLC12A5 | c.1549_1551del p.S517del (on ENST00000454036 / NM_001134771.2; = p.S494del on NM_020708.5) | In Frame Del (DEL) | VAF 225/719 reads (31%) | called by mutect2, pindel, varscan2
- SOX1 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 62/593 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.286); called by muse, varscan2
- SPAG8 | c.164dup p.S56Ifs*27 | Frame Shift Ins (INS) | VAF 45/284 reads (16%) | called by mutect2, pindel, varscan2
- SRCAP | c.6490T>A p.Y2164N | Missense Mutation (SNP) | VAF 177/315 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STK26 | c.372G>T p.M124I | Missense Mutation (SNP) | VAF 11/203 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- SYMPK | c.1329A>C p.E443D | Missense Mutation (SNP) | VAF 274/290 reads (94%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNE2 | c.8126T>C p.L2709S | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TAL1 | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- TAL1 | c.397G>T p.G133C | Missense Mutation (SNP) | VAF 73/549 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- TGM2 | c.1385T>C p.L462P | Missense Mutation (SNP) | VAF 94/816 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- TMEM266 | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 49/312 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- TNXB | c.1730A>C p.E577A | Missense Mutation (SNP) | VAF 293/460 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TRAPPC12 | c.2087A>G p.N696S | Missense Mutation (SNP) | VAF 24/446 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UNC93B1 | c.996_1041del p.F332Lfs*102 | Frame Shift Del (DEL) | VAF 82/347 reads (24%) | called by mutect2, pindel, varscan2
- VAV3 | c.1618C>G p.Q540E | Missense Mutation (SNP) | VAF 38/228 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- WDR33 | c.1239T>G p.D413E | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ZBTB1 | c.1898G>A p.R633K (on ENST00000554015 / NM_001123329.1; = p.S633N on NM_014950.3) | Missense Mutation (SNP) | VAF 184/273 reads (67%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ZBTB7A | c.1375G>A p.V459M | Missense Mutation (SNP) | VAF 198/544 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- ZFAND4 | c.1259G>T p.C420F | Missense Mutation (SNP) | VAF 107/322 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF420 | c.10-1G>C p.X4_splice | Splice Site (SNP) | VAF 99/180 reads (55%) | called by muse, mutect2, varscan2
- ZNF7 | c.1457A>C p.Q486P | Missense Mutation (SNP) | VAF 80/400 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ZNF773 | c.394G>T p.V132F | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTSL3 | c.1527C>T p.R509= | Silent (SNP) | VAF 47/249 reads (19%) | catalogued as rs564700676, COSV54440714; called by muse, mutect2, varscan2
- AJM1 | c.474C>T p.P158= | Silent (SNP) | VAF 30/161 reads (19%) | catalogued as rs1320797651; called by muse, mutect2, varscan2
- ANKRD27 | c.2322C>T p.N774= | Silent (SNP) | VAF 81/530 reads (15%) | catalogued as rs763541677; called by muse, mutect2, varscan2
- AP2A2 | c.1449C>T p.F483= | Silent (SNP) | VAF 51/230 reads (22%) | catalogued as rs747626477, COSV59960049; called by muse, mutect2, varscan2
- ARSA | c.759G>T p.L253= | Silent (SNP) | VAF 290/292 reads (99%) | catalogued as COSV53350273; called by muse, mutect2, varscan2
- BRSK2 | c.888G>A p.E296= | Silent (SNP) | VAF 124/349 reads (36%) | catalogued as COSV100373196; called by muse, mutect2, varscan2
- CAMK2D | c.921T>G p.T307= | Silent (SNP) | VAF 110/221 reads (50%) | called by muse, mutect2, varscan2
- CCDC189 | c.324A>C p.L108= | Silent (SNP) | VAF 36/454 reads (8%) | called by muse, mutect2
- CCNE1 | c.1068T>C p.D356= | Silent (SNP) | VAF 65/454 reads (14%) | catalogued as rs367679106; called by muse, mutect2, varscan2
- CDH23 | c.6384T>C p.G2128= | Silent (SNP) | VAF 90/378 reads (24%) | catalogued as COSV99819412; called by muse, mutect2, varscan2
- CEP350 | c.7053C>T p.H2351= | Silent (SNP) | VAF 58/219 reads (26%) | catalogued as rs749229723; called by muse, mutect2, varscan2
- CRTC3 | c.84G>A p.E28= | Silent (SNP) | VAF 43/298 reads (14%) | called by muse, mutect2, varscan2
- DAPK2 | c.258C>A p.V86= | Silent (SNP) | VAF 284/284 reads (100%) | called by muse, mutect2, varscan2
- DGKG | c.1035C>T p.S345= | Silent (SNP) | VAF 193/449 reads (43%) | catalogued as rs749215718, COSV53965863; called by muse, mutect2, varscan2
- DPY19L1 | c.777G>A p.Q259= | Silent (SNP) | VAF 205/224 reads (92%) | catalogued as rs1354377147; called by muse, mutect2, varscan2
- EHD1 | c.165C>T p.F55= | Silent (SNP) | VAF 330/330 reads (100%) | called by muse, mutect2, varscan2
- FREM3 | c.3709C>A p.R1237= | Silent (SNP) | VAF 192/356 reads (54%) | called by muse, mutect2, varscan2
- GFOD1 | c.780C>T p.A260= | Silent (SNP) | VAF 263/370 reads (71%) | catalogued as rs754200124; called by muse, mutect2, varscan2
- IGKV1D-17 | c.270G>A p.G90= | Silent (SNP) | VAF 299/337 reads (89%) | called by muse, mutect2, varscan2
- KCTD8 | c.96C>T p.A32= | Silent (SNP) | VAF 228/440 reads (52%) | catalogued as rs769210211, COSV100760252; called by muse, mutect2, varscan2
- LRRC4B | c.1497C>T p.P499= | Silent (SNP) | VAF 384/400 reads (96%) | catalogued as rs1434657460, COSV100975841, COSV65350297; called by muse, mutect2, varscan2
- MCF2L2 | c.579C>T p.H193= | Silent (SNP) | VAF 42/323 reads (13%) | catalogued as rs140697821; called by muse, mutect2, varscan2
- MYO10 | c.4011G>A p.L1337= | Silent (SNP) | VAF 40/798 reads (5%) | called by muse, mutect2
- NFATC4 | c.2196C>T p.C732= | Silent (SNP) | VAF 220/220 reads (100%) | catalogued as rs141569636, COSV51603826; called by muse, mutect2, varscan2
- NLRP12 | c.882C>T p.D294= | Silent (SNP) | VAF 115/290 reads (40%) | catalogued as rs147080557, CM1111600; called by muse, mutect2, varscan2
- NPHS1 | c.2259C>T p.V753= | Silent (SNP) | VAF 125/324 reads (39%) | catalogued as rs766951918; called by muse, mutect2, varscan2
- OBSCN | c.17463G>A p.P5821= | Silent (SNP) | VAF 255/397 reads (64%) | catalogued as rs765645372; called by muse, mutect2, varscan2
- OR51M1 | c.687C>T p.S229= | Silent (SNP) | VAF 100/471 reads (21%) | called by muse, mutect2, varscan2
- OR6F1 | c.144G>A p.L48= | Silent (SNP) | VAF 29/261 reads (11%) | called by muse, mutect2, varscan2
- PCDHA11 | c.1572C>T p.H524= | Silent (SNP) | VAF 108/654 reads (17%) | catalogued as rs1554164570, COSV56536366; called by muse, mutect2, varscan2
- PDGFC | c.277A>C p.R93= | Silent (SNP) | VAF 140/288 reads (49%) | called by muse, mutect2, varscan2
- PRDM2 | c.378T>C p.T126= | Silent (SNP) | VAF 62/194 reads (32%) | called by muse, mutect2
- RBM19 | c.1497G>A p.K499= | Silent (SNP) | VAF 329/330 reads (100%) | catalogued as rs1351942891; called by muse, mutect2, varscan2
- SLC12A8 | c.255C>T p.A85= | Silent (SNP) | VAF 153/515 reads (30%) | catalogued as rs1190817586; called by muse, mutect2, varscan2
- SMOC2 | c.837G>A p.P279= (on ENST00000356284 / NM_001166412.2; = p.P290= on NM_022138.3) | Silent (SNP) | VAF 36/325 reads (11%) | catalogued as rs376609544; called by muse, mutect2, varscan2
- SOX18 | c.750G>A p.A250= | Silent (SNP) | VAF 104/1239 reads (8%) | called by muse, mutect2
- ST8SIA4 | c.868A>C p.R290= | Silent (SNP) | VAF 82/247 reads (33%) | catalogued as COSV51508323, COSV51509997; called by muse, mutect2, varscan2
- TFAP2E | c.357G>A p.P119= | Silent (SNP) | VAF 182/602 reads (30%) | catalogued as rs774890111; called by muse, mutect2, varscan2
- TRIM16L | c.840G>A p.G280= | Silent (SNP) | VAF 141/292 reads (48%) | called by muse, mutect2, varscan2
- UNC13A | c.1926C>T p.F642= | Silent (SNP) | VAF 314/446 reads (70%) | catalogued as rs780011051, COSV53211999; called by muse, mutect2, varscan2
- AL121718.1 | n.317G>A | RNA (SNP) | VAF 34/160 reads (21%) | catalogued as rs964782907; called by muse, mutect2, varscan2
- B4GALT3 | c.-160-409T>G | Intron (SNP) | VAF 71/351 reads (20%) | called by muse, mutect2, varscan2
- MIR9-1 | chr1:156416769 C>T | 3'Flank (SNP) | VAF 38/207 reads (18%) | catalogued as rs202145394, COSV59484779; called by muse, mutect2, varscan2
- SLC9A9 | c.*791C>A | 3'UTR (SNP) | VAF 156/410 reads (38%) | catalogued as rs556404248; called by muse, mutect2, varscan2
- SRP9 | c.142-181T>A | Intron (SNP) | VAF 49/246 reads (20%) | called by muse, mutect2, varscan2
